Surgical pathology report (de-identified scan), TCGA case TCGA-W3-AA1Q, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site  John Wayne Cancer Center, specimen TCGA-W3-AA1Q-06A (Metastatic).

CLINICAL HISTORY

Preop diagnosis: Metastatic melanoma-tumor left adrenal gland.

GROSS DESCRIPTION

1. Labeled "12th rib left": The specimen consists of a portion of rib which measures 11.5 x 1.2 x 0.6 cm. Representative sections submitted after decalcification as 1A. (Per TSS, 1 month prior at outside facility)
2. Labeled "left adrenal gland": The specimen consists of a previously incised tumor which measures 8 x 5 x 3.7. It is invested by a thin layer of fibrofatty tissue which in areas measures less than a millimeter in thickness. On one aspect residual yellow adrenal tissue is identified which measures 3 x 6 cm. It varies in thickness from less than 1 millimeter to 5 mm. Cut section of the tumor is gray tan. Central portion appears to be previously removed. Representative sections submitted as 2A and B.
- Microscopic sections are prepared and interpreted.

DIAGNOSIS

1. LABELED "12TH RIB LEFT":
- DECALCIFICATION PENDING.
2. LABELED "LEFT ADRENAL GLAND":
- METASTATIC MELANOMA FORMING A TUMOR, 8 CM IN GREATEST DIMENSION, INVOLVING ADIPOSE TISSUE.
- TUMOR ABUTS AND FOCALLY INVADES ADRENAL CAPSULE, BUT DOES NOT EXTEND INTO PARENCHYMA.

ADDENDUM

DIAGNOSIS:

1. LABELED "12TH RIB, LEFT":
- NEGATIVE FOR MALIGNANCY.

signed Electronically signed by:

** END OF REPORT **

Source: NCI Genomic Data Commons file 311b1979-137a-4066-bfba-bbbe227908c2 (TCGA-W3-AA1Q.A4B45987-C6B8-4CA0-8CCA-FAE49C1A6EB1.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).